Somatic mutation profile of tumor specimen BLGSP-71-08-00026-01B (aliquot BLGSP-71-08-00026-01B-01D-A663-33) from CGCI case BLGSP-71-08-00026, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male.
Specimen BLGSP-71-08-00026-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa3e2b70-a13b-4de7-a591-584ee408de99.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-08-00026-10A (Blood Derived Normal), aliquot BLGSP-71-08-00026-10A-01D-A663-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41050a55-90d4-404a-981e-8ce358f0d8bc

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, 5'UTR 2, Frame Shift Ins 2, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMP7 | c.250C>G p.L84V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1276059448, COSV67781992; called by muse, varscan2
- ID3 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65800754, COSV65801030, COSV65801279; called by muse, varscan2
- TCL1A | c.113C>G p.T38S | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs201228671, COSV68085105, COSV68085114, COSV68085683; called by muse, varscan2
- BMP7 | c.249G>T p.M83I | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, varscan2
- DDX3X | c.556_557dup p.M186Ifs*35 (on ENST00000399959; = p.M187Ifs*35 on NM_001356.5) | Frame Shift Ins (INS) | VAF 54/180 reads (30%) | called by mutect2, pindel, varscan2
- MYC | c.458A>G p.Q153R (on ENST00000377970; = p.Q168R on NM_002467.6) | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.656); called by muse, varscan2
- TCL1A | c.116T>G p.I39S | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.321); called by muse, varscan2
- TMEM30A | c.653dup p.G219Wfs*10 | Frame Shift Ins (INS) | VAF 42/204 reads (21%) | called by mutect2, pindel, varscan2
- MYC | c.741C>T p.T247= (on ENST00000377970; = p.T262= on NM_002467.6) | Silent (SNP) | VAF 7/197 reads (4%) | called by muse, mutect2
- AC072022.2 | c.-67C>A | 5'UTR (SNP) | VAF 17/69 reads (25%) | catalogued as rs189043889, COSV69202469, COSV69202958; called by muse, mutect2, varscan2
- EBF1 | c.-186T>A | 5'UTR (SNP) | VAF 15/72 reads (21%) | called by muse, mutect2, varscan2
- TMSB4X | c.-17+112C>G | Intron (SNP) | VAF 28/75 reads (37%) | called by muse, mutect2, varscan2
